MMRF case MMRF_2541 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9c7c0020-7cd3-4e0f-86cd-b474f82fb732

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.7 years (21,081 days); ISS stage: II; Days to last known disease status: 585 days (1.6 years); Days to last follow up: 585 days (1.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Carfilzomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 158 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 385 days (1.1 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 561 days (1.5 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 571 days (1.6 years); Days to treatment end: 662 days (1.8 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 571 days (1.6 years); Days to treatment end: 620 days (1.7 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 621 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 666 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21: M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 27.9 g/L; Immunoglobulin M 0.269 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 5.32 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 8.5 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.13 mg/dL.
- Day 63 (ECOG 0): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 2.98 g/L; Immunoglobulin A 16.9 g/L; Immunoglobulin M 0.358 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.8 g/dL; Glucose 6.6 mmol/L.
- Day 183 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 3.53 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.343 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 4.88 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 5.89 mmol/L.
- Day 259 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 9.45 g/L; Immunoglobulin A 1.07 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 4 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 7.8 g/dL; Glucose 4.73 mmol/L.
- Day 301 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 6.97 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 6.22 mmol/L.
- Day 406 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 490 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 3.56 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 7.21 mmol/L.
- Day 585 (ECOG 1): M Protein 3.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 3.62 g/L; Immunoglobulin A 34.7 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 5.8 µg/mL; Lactate Dehydrogenase 4.55 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 1 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 28 g/L; Total Protein 9.4 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -21: Weight: 51 kg; Height: 149 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2541_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_2541_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
